Surgical pathology report (de-identified scan), TCGA case TCGA-DU-7299, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-7299-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

Surgical Pathology Report

[REDACTED]

=====

CLINICAL HISTORY

[REDACTED] man with recent onset seizure, has a left parietal occipital tumor.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain mass, biopsy

B: Brain, resection

PATHOLOGICAL DIAGNOSIS:

A and B. Brain, parieto-occipital, excision: Gemistocytic astrocytoma, diffusely infiltrating, anaplastic. MIB-1 proliferation index: 10%.

See comment.

COMMENT

The specimens contain cerebral cortex and adjacent white matter diffusely infiltrated by an astrocytic neoplastic proliferation, which is focally cellular and pleomorphic. Many of the nuclei are naked, but many other have a gemistocytic phenotype. Mitotic figures are found with difficulty, but are present. There is no microvascular cellular proliferation or necrosis. The MIB-1 proliferation index is greater than 10%.

Electronically Signed Out

[REDACTED]

INTRA-OPERATIVE CONSULTATION

Brain mass, biopsy, touch prep and smears: Glioma. [REDACTED]

[REDACTED]

[page 2 of 2]
GROSS DESCRIPTION

A. Received fresh, four fragments, 2.2 cm. across in aggregate. Semi firm,

tannish-yellow, poorly demarcated cerebral cortex. In total, A1-A3.

B.

SPECIMEN: Brain mass.

FIXATIVE: Formalin.

GENERAL: A 2.0 x 1.5 x 0.4 cm. aggregate of several irregularly shaped

fragments of gray-tan to gray-white tissue.

SECTIONS: B1 - all submitted.

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates a gliofibrillary background with abundant gemistocytes. More than 45% of the tumor cells over express the p53

protein. With the MIB-1 a proliferation index greater than 10% is determined

in the more active areas.

These results support the diagnosis of an aggressive astrocytoma.

Billing Fee Code(s):

Histo Data

Part A: Brain mass, biopsy

Taken:	Received:	Block	Ordered	Comment
Stain/cnt				
H/E x 1		1		
mGFAP-DA x 1		2		
H/E x 1		2		
MIB1-DA x 1		2		
P53DO7 x 1		2		
Rct 1 H/E x 1		2		
Rct 2 H/E x 1		2		
Rct 3 H/E x 1		2		
H/E x 1		3		
Rct 1 H/E x 1		3		
Rct 2 H/E x 1		3		
Rct 3 H/E x 1		3		

Part B: Brain resection

Taken:	Received:	Block	Ordered	Comment
Stain/cnt				
mGFAP-DA x 1		1		
H/E x 1		1		
MIB1-DA x 1		1		
P53DO7 x 1		1		

*** End of Report ***

Source: NCI Genomic Data Commons file 1491e8f2-62b7-48e3-b444-71a2e9f88d8c (TCGA-DU-7299.36CA34B7-04EE-4CBB-ABA8-1171AE076ABD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).